Somatic mutation profile of tumor specimen TCGA-DM-A1HB-01A (aliquot TCGA-DM-A1HB-01A-21D-A183-10) from TCGA case TCGA-DM-A1HB, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Transverse colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 75.9 years (27,708 days).
Specimen TCGA-DM-A1HB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24bab32c-9a3a-4939-b358-3922145a290b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DM-A1HB-10A (Blood Derived Normal), aliquot TCGA-DM-A1HB-10A-01D-A183-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af3558bc-428a-416d-8c0d-94a0e15b2abe

The open-access MAF lists 1,415 somatic variants for this specimen: 1,055 protein-altering or splice-affecting, 334 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 735, Silent 334, Frame Shift Del 187, Frame Shift Ins 47, Nonsense Mutation 37, Splice Site 25, Intron 12, Splice Region 9, In Frame Del 9, RNA 9, Translation Start Site 6, 3'UTR 3.

Variants (750 of 1,415; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.6229C>T p.R2077W | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs61750645, CM003395, CM970021; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ACADM | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 157/455 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs373715782, CM051829; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATM | c.2413C>T p.R805* | Nonsense Mutation (SNP) | VAF 96/224 reads (43%) | catalogued as rs780619951, CM960099, COSV53736642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BMPR2 | c.377A>G p.N126S | Missense Mutation (SNP) | VAF 88/277 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs863223426, CM106873, COSV101001618; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BSND | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs74315289, CM035675; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ETV6 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.121); catalogued as rs724159947, CM150819, COSV67147991; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- EXT2 | c.244del p.D82Ifs*30 (on ENST00000343631; = p.D115Ifs*30 on NM_000401.3) | Frame Shift Del (DEL) | VAF 70/195 reads (36%) | catalogued as rs1555002457; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 56/174 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GLDC | c.2311G>A p.G771R | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs386833553, CM061033, COSV58683845; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- HPSE2 | c.57dup p.A20Rfs*45 | Frame Shift Ins (INS) | VAF 44/176 reads (25%) | catalogued as rs778121647; ClinVar: pathogenic; called by mutect2, varscan2
- IQSEC2 | c.804del p.Y269Tfs*3 (on ENST00000642864 / NM_001111125.3; = p.Y64Tfs*3 on NM_015075.2) | Frame Shift Del (DEL) | VAF 22/45 reads (49%) | catalogued as rs886041481, CD162113; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- MSH6 | c.3312dup p.G1105Wfs*3 | Frame Shift Ins (INS) | VAF 78/294 reads (27%) | catalogued as rs267608092; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- MYO15A | c.1185del p.E396Rfs*48 | Frame Shift Del (DEL) | VAF 103/342 reads (30%) | catalogued as rs772536599; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- NOTCH2 | c.6909dup p.I2304Hfs*9 | Frame Shift Ins (INS) | VAF 28/87 reads (32%) | catalogued as rs771237928; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 12/21 reads (57%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 55/158 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TYR | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 103/320 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs61754375, CM920694, COSV54474139; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1970G>A p.R657H | Missense Mutation (SNP) | VAF 119/322 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs372629661; called by muse, mutect2, varscan2
- A4GNT | c.962G>T p.R321M | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV52629796; called by muse, mutect2, varscan2
- ABCA2 | c.3545C>T p.A1182V (on ENST00000614293; = p.A1152V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/180 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs923209488; called by muse, mutect2, varscan2
- ABCA3 | c.2235del p.S746Pfs*15 | Frame Shift Del (DEL) | VAF 25/92 reads (27%) | catalogued as COSV57056003; called by mutect2, pindel, varscan2
- AC098582.1 | c.2549C>T p.T850M | Missense Mutation (SNP) | VAF 92/355 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs146977820; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 110/150 reads (73%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM2 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs752769589, COSV55865495; called by muse, mutect2, varscan2
- ADCY1 | c.1019C>T p.T340M | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as rs183468184; called by muse, mutect2, varscan2
- ADCY2 | c.2681C>T p.P894L | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57873811; called by muse, mutect2, varscan2
- ADGRB1 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV60102020; called by muse, mutect2, varscan2
- ADPRS | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 65/191 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs201025691, COSV99255514; called by muse, mutect2, varscan2
- AGBL5 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs955009057, COSV59936213; called by muse, mutect2, varscan2
- AGRN | c.2839G>A p.E947K | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.688); catalogued as rs942708644; called by muse, mutect2, varscan2
- AHCTF1 | c.1142C>T p.T381M (on ENST00000366508; = p.T355M on NM_015446.5) | Missense Mutation (SNP) | VAF 90/235 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs760662305; called by muse, mutect2, varscan2
- AHSA1 | c.756G>T p.M252I | Missense Mutation (SNP) | VAF 68/226 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs749961382; called by muse, mutect2, varscan2
- ALG12 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 50/190 reads (26%) | PolyPhen possibly damaging (0.671); catalogued as rs751656286, COSV100427091; called by muse, mutect2, varscan2
- AMBRA1 | c.239C>T p.T80M | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1328894371; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMOTL1 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as rs756534459, COSV58565076; called by muse, mutect2, varscan2
- ANKAR | c.583dup p.S195Ffs*4 | Frame Shift Ins (INS) | VAF 9/20 reads (45%) | catalogued as rs781010564; called by mutect2, varscan2
- ANKRD12 | c.4633A>G p.T1545A | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs993129579; called by muse, mutect2, varscan2
- ANKRD34A | c.1241T>C p.L414P | Missense Mutation (SNP) | VAF 65/241 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs782102250; called by muse, mutect2, varscan2
- AP3B2 | c.1874G>T p.G625V | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55609554, COSV99915901; called by muse, varscan2
- APOE | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as rs937063425, COSV52986053; called by muse, mutect2
- APOF | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.457); catalogued as rs1477579897; called by muse, mutect2, varscan2
- ARHGEF25 | c.92dup p.R32Tfs*2 | Frame Shift Ins (INS) | VAF 42/119 reads (35%) | catalogued as rs748506876; called by mutect2, varscan2
- ARID2 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs896638040, COSV57600821, COSV57606795; called by muse, mutect2, varscan2
- ARL3 | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 84/222 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.431); catalogued as rs150077149; called by muse, mutect2, varscan2
- ATG2A | c.4648C>T p.P1550S | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65968686; called by muse, varscan2
- ATP13A5 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 70/245 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs776380026, COSV60868282; called by muse, varscan2
- ATP2B2 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs754821593, COSV59508021; called by muse, mutect2, varscan2
- ATP2B2 | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762962570; called by muse, varscan2
- ATRNL1 | c.4037C>A p.A1346D | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58100368; called by muse, mutect2, varscan2
- B4GALNT3 | c.1930G>A p.D644N | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs369288672; called by muse, varscan2
- B4GALNT4 | c.2926C>T p.R976W | Missense Mutation (SNP) | VAF 73/217 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs1163396980, COSV100327933, COSV57326323; called by muse, mutect2, varscan2
- BARHL2 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs770520511, COSV64982281; called by muse, mutect2, varscan2
- BCAS3 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.973); catalogued as rs751704466, COSV66769841; called by muse, mutect2, varscan2
- BICDL2 | c.590C>T p.T197M | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs764724643, COSV54155556, COSV54157562; called by muse, mutect2, varscan2
- BNC2 | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 112/258 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs754309176; called by muse, mutect2, varscan2
- BNIP5 | c.995T>C p.L332P | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV71325784; called by muse, mutect2, varscan2
- BRSK1 | c.1135del p.R379Gfs*9 | Frame Shift Del (DEL) | VAF 24/70 reads (34%) | catalogued as rs746043904, COSV58665984; called by mutect2, varscan2
- BTBD2 | c.412G>A p.V138M | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs141098024; called by muse, mutect2, varscan2
- C20orf85 | c.269del p.P90Qfs*19 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | catalogued as rs777635732, COSV100959338, COSV64519981; called by mutect2, pindel, varscan2
- C2orf80 | c.453G>T p.Q151H | Missense Mutation (SNP) | VAF 119/338 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as COSV58018344; called by muse, mutect2, varscan2
- CA11 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 75/168 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.381); catalogued as COSV50033879; called by muse, mutect2, varscan2
- CACNA1A | c.6675del p.P2227Rfs*45 (on ENST00000614285; = p.P2227Rfs*285 on NM_000068.4) | Frame Shift Del (DEL) | VAF 20/61 reads (33%) | catalogued as rs1555730604, COSV100801821; called by mutect2, pindel, varscan2
- CACNA1C | c.229A>G p.S77G | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.217); catalogued as rs1394254631; called by muse, mutect2, varscan2
- CACNG5 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs747666687, COSV50055403; called by muse, varscan2
- CAMK1 | c.600T>G p.D200E | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV56539946; called by muse, mutect2, varscan2
- CARNMT1 | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 75/217 reads (35%) | catalogued as rs190060534, COSV65193632; called by muse, mutect2, varscan2
- CBARP | c.392C>T p.A131V (on ENST00000382477; = p.A137V on NM_152769.3) | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs534006111, COSV99289583; called by muse, mutect2, varscan2
- CBLB | c.2594G>A p.G865D | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.058); catalogued as rs995686990; called by muse, mutect2, varscan2
- CCDC24 | c.757G>T p.G253W | Missense Mutation (SNP) | VAF 61/192 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762726501, COSV62210088; called by muse, mutect2, varscan2
- CCPG1 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1447463002; called by muse, mutect2, varscan2
- CCR4 | c.604A>G p.S202G | Missense Mutation (SNP) | VAF 69/189 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV58383407; called by muse, mutect2, varscan2
- CCR6 | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.75); catalogued as rs752574574, COSV59474388; called by muse, mutect2, varscan2
- CDC42BPB | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as rs551755307, COSV63476844; called by muse, mutect2, varscan2
- CDH23 | c.8032C>T p.R2678C | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56476917; called by muse, mutect2, varscan2
- CDH24 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs955239180, COSV52975829; called by muse, mutect2, varscan2
- CDKN2A | c.456A>G p.S152= | Splice Region (SNP) | VAF 10/39 reads (26%) | catalogued as COSV58710245; called by muse, mutect2, varscan2
- CDYL | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as rs750626007; called by muse, mutect2, varscan2
- CELSR3 | c.6637C>T p.R2213W | Missense Mutation (SNP) | VAF 114/260 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV50945341; called by muse, mutect2, varscan2
- CELSR3 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1307389939; called by muse, mutect2, varscan2
- CEP120 | c.2648G>A p.R883H | Missense Mutation (SNP) | VAF 271/808 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as rs368260761; called by muse, mutect2, varscan2
- CEP135 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 229/506 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs763361090, COSV57258605; called by muse, mutect2, varscan2
- CFAP45 | c.657del p.E220Nfs*12 | Frame Shift Del (DEL) | VAF 195/644 reads (30%) | catalogued as rs778733437; called by mutect2, pindel, varscan2
- CFHR5 | c.690T>A p.N230K | Missense Mutation (SNP) | VAF 152/481 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as rs781094025; called by muse, mutect2, varscan2
- CHAF1A | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 83/312 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs573779621, COSV100011346; called by muse, mutect2, varscan2
- CHD3 | c.5438C>T p.A1813V (on ENST00000330494 / NM_001005273.3; = p.A1779V on NM_005852.4) | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.112); catalogued as rs1336103222; called by muse, mutect2, varscan2
- CHD8 | c.7112del p.N2371Ifs*6 (on ENST00000646647 / NM_001170629.2; = p.N2092Ifs*6 on NM_020920.4) | Frame Shift Del (DEL) | VAF 50/176 reads (28%) | catalogued as rs751094013; called by mutect2, varscan2
- CHGB | c.1400T>C p.L467P | Missense Mutation (SNP) | VAF 62/129 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1012057050; called by muse, mutect2, varscan2
- CHPF2 | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.786); catalogued as rs746382000, COSV50397494; called by muse, mutect2, varscan2
- CIC | c.2353del p.A785Pfs*139 | Frame Shift Del (DEL) | VAF 20/67 reads (30%) | catalogued as rs34000070, COSV99359651; called by mutect2, pindel, varscan2
- CIT | c.2695G>A p.A899T | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1475867999, COSV55869422; called by muse, mutect2
- CKLF | c.447dup p.E150Rfs*12 (on ENST00000264001 / NM_016951.4; = p.E65Rfs*12 on NM_016326.3) | Frame Shift Ins (INS) | VAF 70/238 reads (29%) | catalogued as rs754415052; called by mutect2, varscan2
- CLK3 | c.755G>A p.R252H (on ENST00000395066 / NM_001130028.1; = p.R104H on NM_003992.4) | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.813); catalogued as rs1429799732, COSV61412783; called by muse, mutect2, varscan2
- CLPB | c.1655A>G p.H552R | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV53632373; called by muse, mutect2, varscan2
- CMTM6 | c.41A>G p.D14G | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1385310134; called by muse, mutect2, varscan2
- CNTNAP4 | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 73/171 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs148104897; called by muse, mutect2, varscan2
- CNTNAP4 | c.2468C>T p.T823I | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56695058; called by muse, mutect2, varscan2
- CNTRL | c.6508A>G p.T2170A | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV53051602; called by muse, mutect2, varscan2
- COL11A2 | c.2326C>T p.R776C (on ENST00000341947 / NM_080680.3; = p.R669C on NM_080679.2) | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs776701792, COSV59493332; called by muse, mutect2, varscan2
- COL18A1 | c.1521C>A p.F507L (on ENST00000359759 / NM_130444.3; = p.F272L on NM_030582.4) | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs890511521; called by muse, mutect2, varscan2
- COL18A1 | c.1868C>T p.A623V (on ENST00000359759 / NM_130444.3; = p.A388V on NM_030582.4) | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773440175, COSV62701676; called by muse, mutect2, varscan2
- COL22A1 | c.3571C>A p.P1191T | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs751827116, COSV57328137; called by muse, mutect2, varscan2
- COL27A1 | c.4285C>T p.R1429W | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs200170613; called by muse, mutect2, varscan2
- COL8A1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.474); catalogued as rs769320857, COSV53732499, COSV53740065; called by muse, mutect2, varscan2
- COLEC12 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 185/506 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs905694157, COSV68369756; called by muse, mutect2, varscan2
- CORO2B | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1302425549, COSV99963044; called by muse, mutect2, varscan2
- CPA5 | c.1041C>T p.Y347= | Splice Region (SNP) | VAF 38/113 reads (34%) | catalogued as rs1212719630; called by muse, mutect2, varscan2
- CRTAM | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.25); catalogued as rs1467824849, COSV57069745; called by muse, mutect2, varscan2
- CSTF2T | c.842C>G p.T281S | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.05); catalogued as rs761937055; called by muse, mutect2, varscan2
- CTBP1 | c.1105G>A p.V369I | Missense Mutation (SNP) | VAF 63/189 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs138269585; called by muse, mutect2, varscan2
- CTDP1 | c.1982C>T p.T661M | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs374004081; called by muse, mutect2, varscan2
- CUL1 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.151); catalogued as rs748809924; called by muse, mutect2, varscan2
- CUL9 | c.4360C>T p.R1454W | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs557163267; called by muse, mutect2, varscan2
- CYB5R2 | c.433del p.T145Hfs*8 | Frame Shift Del (DEL) | VAF 45/140 reads (32%) | catalogued as rs775988957; called by mutect2, varscan2
- DAB2IP | c.3073dup p.H1025Pfs*4 (on ENST00000408936; = p.H997Pfs*4 on NM_032552.3) | Frame Shift Ins (INS) | VAF 23/64 reads (36%) | catalogued as rs751187768; called by mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 79/191 reads (41%) | catalogued as COSV99245498; called by mutect2, varscan2
- DBT | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.301); catalogued as COSV64496151; called by muse, mutect2, varscan2
- DCC | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs780738407, COSV59095079, COSV59142839; called by muse, mutect2, varscan2
- DCHS1 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs755687394, COSV100201769, COSV55030160, COSV55041984; called by muse, mutect2, varscan2
- DCLK1 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 35/89 reads (39%) | catalogued as rs754197263; called by muse, mutect2, varscan2
- DCXR | c.28G>T p.V10L | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs776627238; called by muse, mutect2, varscan2
- DDHD1 | c.1174C>T p.R392W (on ENST00000323669; = p.R589W on NM_030637.3) | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as rs780032756, COSV60361555; called by muse, mutect2, varscan2
- DDO | c.770G>A p.R257Q (on ENST00000368924 / NM_001368172.1; = p.R198Q on NM_004032.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); catalogued as rs755822127, COSV64470442; called by muse, mutect2, varscan2
- DDX39B | c.736-3del | Splice Region (DEL) | VAF 30/65 reads (46%) | catalogued as rs755280697; called by mutect2, varscan2
- DDX46 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 76/206 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs779907408; called by muse, varscan2
- DENND5A | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.053); catalogued as rs375955901, COSV60232054, COSV60234949; called by muse, mutect2, varscan2
- DGLUCY | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs759389819; called by muse, mutect2, varscan2
- DIP2C | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.676); catalogued as rs373279565; called by muse, mutect2, varscan2
- DIS3L | c.632G>A p.R211Q (on ENST00000319212 / NM_001143688.3; = p.R128Q on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs111953940; called by muse, mutect2, varscan2
- DNAH10 | c.4945G>A p.V1649I (on ENST00000409039; = p.V1588I on NM_207437.3) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.604); catalogued as rs756639864, COSV68994810; called by muse, mutect2, varscan2
- DNAH11 | c.2832del p.Q945Kfs*4 | Frame Shift Del (DEL) | VAF 49/184 reads (27%) | catalogued as COSV60968530; called by mutect2, pindel, varscan2
- DNAH17 | c.10226C>T p.A3409V | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs199512383; called by muse, mutect2, varscan2
- DNAJB9 | c.268G>T p.G90* | Nonsense Mutation (SNP) | VAF 39/132 reads (30%) | catalogued as COSV50812587; called by muse, mutect2, varscan2
- DNASE1L2 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1448761419, COSV57039256; called by muse, mutect2, varscan2
- DNMBP | c.3371G>A p.R1124H | Missense Mutation (SNP) | VAF 128/285 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1474832061, COSV60626481; called by muse, mutect2, varscan2
- DOCK10 | c.1122dup p.D375Rfs*6 | Frame Shift Ins (INS) | VAF 64/256 reads (25%) | catalogued as rs750262341; called by mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 71/167 reads (43%) | catalogued as rs782552436; called by mutect2, varscan2
- DPPA5 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as rs1238480576, COSV64875723, COSV64875816; called by muse, mutect2, varscan2
- DSP | c.4019G>A p.R1340H | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs765247380, COSV65792464; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DST | c.20768G>T p.G6923V (on ENST00000361203 / NM_001374722.1; = p.G4620V on NM_015548.5) | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV55033180; called by muse, mutect2, varscan2
- DTX3 | c.727G>A p.V243I | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as rs201091006, COSV54087089; called by muse, mutect2, varscan2
- DVL2 | c.931A>G p.I311V | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as rs766732685; called by mutect2, varscan2
- DYNC1H1 | c.12763C>T p.R4255C | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs770105370; called by muse, mutect2, varscan2
- DYRK1B | c.1633dup p.Q545Pfs*30 | Frame Shift Ins (INS) | VAF 14/60 reads (23%) | catalogued as rs775499198; called by mutect2, varscan2
- ECEL1 | c.2174C>T p.S725L | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.87); catalogued as rs1000051849; called by muse, mutect2, varscan2
- ECH1 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs764029520, COSV55490066; called by muse, mutect2, varscan2
- EDC4 | c.3568G>A p.A1190T | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV59303531; called by muse, mutect2, varscan2
- EDEM1 | c.1941G>A p.M647I | Missense Mutation (SNP) | VAF 124/372 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs746353703; called by muse, mutect2, varscan2
- EFEMP1 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs374747361; called by muse, mutect2, varscan2
- EIF4A2 | c.1067A>G p.N356S | Missense Mutation (SNP) | VAF 71/158 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV99960922; called by muse, varscan2
- ELMO3 | c.475C>T p.R159C (on ENST00000652269; = p.R106C on NM_024712.5) | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); catalogued as COSV100681712; called by muse, mutect2, varscan2
- ELOA2 | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.758); catalogued as rs375806666; called by muse, mutect2, varscan2
- EMB | c.897G>T p.E299D | Missense Mutation (SNP) | VAF 222/691 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.045); catalogued as COSV57483811; called by muse, mutect2, varscan2
- EME1 | c.1702A>G p.S568G | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs568424837; called by muse, mutect2, varscan2
- EML4 | c.387del p.E130Rfs*43 | Frame Shift Del (DEL) | VAF 34/100 reads (34%) | catalogued as rs770453803; called by mutect2, varscan2
- ENTPD4 | c.638A>G p.H213R | Missense Mutation (SNP) | VAF 87/282 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1260928126, COSV62268630; called by muse, mutect2, varscan2
- ENTPD8 | c.1348G>A p.G450R (on ENST00000371506 / NM_001033113.2; = p.G413R on NM_198585.3) | Missense Mutation (SNP) | VAF 67/175 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs768824242, COSV58163986; called by muse, mutect2, varscan2
- ENTR1 | c.722C>T p.P241L (on ENST00000357365 / NM_001039707.2; = p.P218L on NM_006643.4) | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs779864138, COSV53742740; called by muse, mutect2, varscan2
- EPS8L3 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as rs762350313, COSV100719713; called by muse, mutect2, varscan2
- ERICH6 | c.161A>T p.E54V | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs753770853, COSV55798938; called by mutect2, varscan2
- FAM171A1 | c.1135G>A p.V379I | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0.066); catalogued as rs371933282; called by muse, mutect2, varscan2
- FAM193A | c.2497del p.M833Wfs*23 | Frame Shift Del (DEL) | VAF 97/322 reads (30%) | catalogued as rs768952789; called by mutect2, pindel, varscan2
- FAM53A | c.34C>T p.Q12* | Nonsense Mutation (SNP) | VAF 80/225 reads (36%) | catalogued as COSV57402903; called by muse, mutect2, varscan2
- FAM83G | c.1939C>T p.R647W | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs201668455; called by muse, mutect2, varscan2
- FBLN7 | c.938C>T p.T313M | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374648225; called by muse, mutect2, varscan2
- FBN1 | c.4787G>A p.R1596Q | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as rs769588424, CM074167; called by muse, mutect2, varscan2
- FBN3 | c.3041C>T p.A1014V | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs756579395, COSV54470384; called by muse, mutect2, varscan2
- FER1L5 | c.5776G>A p.D1926N (on ENST00000623019; = p.D1890N on NM_001293083.2) | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.285); catalogued as COSV53840944; called by muse, mutect2
- FGFR1 | c.411G>T p.E137D | Missense Mutation (SNP) | VAF 118/303 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0.029); catalogued as COSV58341492; called by muse, mutect2, varscan2
- FHOD1 | c.2962C>T p.R988W | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747061959; called by muse, mutect2, varscan2
- FIGN | c.732T>G p.S244R | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.044); catalogued as COSV60764012; called by muse, mutect2, varscan2
- FLRT3 | c.502A>G p.T168A | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV53989708; called by muse, mutect2, varscan2
- FLVCR1 | c.200C>A p.P67H | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.275); catalogued as COSV63134418; called by muse, mutect2, varscan2
- FNDC1 | c.4457G>A p.R1486H | Missense Mutation (SNP) | VAF 94/330 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as rs547791202; called by muse, mutect2, varscan2
- FOXD4L6 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 60/400 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.837); catalogued as rs763388402; called by muse, mutect2, varscan2
- FOXJ1 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 78/176 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs770811479; called by muse, mutect2, varscan2
- FRRS1 | c.1174G>T p.A392S | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54920594; called by muse, mutect2, varscan2
- FSD2 | c.1646del p.G549Afs*4 | Frame Shift Del (DEL) | VAF 11/46 reads (24%) | catalogued as rs1246402267; called by mutect2, pindel, varscan2
- FSHB | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.646); catalogued as rs267602841, COSV99569277; called by muse, mutect2, varscan2
- FSTL4 | c.1827-1G>T p.X609_splice | Splice Site (SNP) | VAF 45/125 reads (36%) | catalogued as COSV54781947; called by muse, mutect2, varscan2
- FTCD | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754530912, COSV52427529; called by muse, mutect2, varscan2
- FZD8 | c.2021C>T p.T674M | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs1430720202, COSV65967619; called by muse, mutect2, varscan2
- GAB4 | c.1528C>T p.P510S | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs747170368; called by muse, mutect2, varscan2
- GAMT | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as CS961593, COSV52040707; called by muse, mutect2, varscan2
- GDF5 | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 174/469 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs906176970, CM970644, COSV65500397; called by muse, mutect2, varscan2
- GJA3 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as CM066571, CM162289; called by muse, mutect2, varscan2
- GJA8 | c.263del p.P88Rfs*3 | Frame Shift Del (DEL) | VAF 38/121 reads (31%) | catalogued as COSV53789902; called by mutect2, pindel, varscan2
- GNB1L | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 29/493 reads (6%) | catalogued as COSV61549395; called by muse, mutect2
- GNG12 | c.137A>G p.H46R | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as rs139638442; called by muse, mutect2, varscan2
- GNMT | c.148C>A p.L50I | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs377704687; called by muse, mutect2, varscan2
- GOLGA3 | c.1909C>T p.R637C | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372097416; called by muse, varscan2
- GOLIM4 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 97/272 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1235755308; called by muse, mutect2, varscan2
- GPR132 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs1207390244, COSV61678284; called by muse, mutect2, varscan2
- GPR18 | c.587del p.F196Sfs*2 | Frame Shift Del (DEL) | VAF 62/169 reads (37%) | catalogued as rs748201402; called by mutect2, varscan2
- GREM2 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58956363; called by muse, mutect2, varscan2
- GRIK2 | c.1069A>G p.T357A | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV59711223; called by muse, mutect2, varscan2
- GRIN2A | c.4249C>T p.R1417W | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs369508378; called by muse, mutect2, varscan2
- GRIN2A | c.3613G>A p.E1205K | Missense Mutation (SNP) | VAF 123/360 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs918332999; called by muse, varscan2
- GRIN2A | c.3491C>T p.T1164M | Missense Mutation (SNP) | VAF 70/199 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.703); catalogued as COSV100408207, COSV58031456; called by muse, varscan2
- GRIP2 | c.2615C>T p.P872L (on ENST00000619221; = p.P775L on NM_001080423.4) | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs369531639; called by muse, mutect2, varscan2
- GRN | c.1507C>T p.Q503* | Nonsense Mutation (SNP) | VAF 28/100 reads (28%) | catalogued as CM162421; called by muse, mutect2, varscan2
- GRXCR1 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 74/180 reads (41%) | catalogued as rs767669071; called by muse, mutect2, varscan2
- GSTA1 | c.347A>G p.E116G | Missense Mutation (SNP) | VAF 68/216 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV58016439; called by muse, mutect2, varscan2
- H2BC14 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 39/158 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as rs143108953, COSV60798466; called by muse, mutect2, varscan2
- HAUS8 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs368689437; called by muse, mutect2, varscan2
- HDGF | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1385420300; called by muse, mutect2, varscan2
- HECTD4 | c.9718del p.A3240Rfs*26 | Frame Shift Del (DEL) | VAF 17/57 reads (30%) | catalogued as rs754540615; called by mutect2, pindel, varscan2
- HECTD4 | c.5473G>T p.A1825S | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66397401; called by muse, mutect2, varscan2
- HECW1 | c.3457C>T p.R1153W | Missense Mutation (SNP) | VAF 96/296 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748678471, COSV67840087; called by muse, mutect2, varscan2
- HK3 | c.1159G>A p.V387I | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.5); catalogued as rs1322178837; called by muse, mutect2, varscan2
- HMCN1 | c.6421G>A p.G2141S | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs964866048, COSV99627384; called by muse, mutect2, varscan2
- HMX3 | c.68del p.P23Hfs*100 | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | catalogued as rs779589617; called by mutect2, varscan2
- HNRNPA2B1 | c.7-3dup | Splice Region (INS) | VAF 13/86 reads (15%) | catalogued as rs759915055; called by pindel, varscan2
- HNRNPH2 | c.875A>G p.H292R | Missense Mutation (SNP) | VAF 60/95 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.176); catalogued as COSV54510302; called by muse, mutect2, varscan2
- HOXC5 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs777703309; called by muse, mutect2, varscan2
- HPS4 | c.976G>A p.G326R | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); catalogued as rs377326385; called by muse, mutect2, varscan2
- HSF1 | c.257A>G p.Q86R | Missense Mutation (SNP) | VAF 61/187 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV68822067; called by muse, mutect2, varscan2
- HSPG2 | c.6445G>A p.G2149S | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs561417019; called by muse, mutect2, varscan2
- HYDIN | c.9985G>A p.V3329M | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs764434157; called by muse, mutect2, varscan2
- IFFO1 | c.1089del p.R364Gfs*47 (on ENST00000396840 / NM_001330324.2; = p.R367Gfs*47 on NM_080730.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 42/78 reads (54%) | catalogued as rs750779916, COSV60737300; called by mutect2, pindel, varscan2
- IFT140 | c.938T>C p.L313P | Missense Mutation (SNP) | VAF 71/160 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101276328; called by muse, mutect2, varscan2
- IGHV5-51 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs147695427; called by muse, mutect2, varscan2
- IL22RA2 | c.575del p.N192Mfs*4 | Frame Shift Del (DEL) | VAF 73/263 reads (28%) | catalogued as rs756450081; called by mutect2, varscan2
- IL6R | c.1336A>C p.N446H | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV59818502; called by muse, mutect2, varscan2
- ILVBL | c.869T>C p.L290P | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs768344024; called by muse, mutect2, varscan2
- INTS9 | c.1936C>T p.R646* | Nonsense Mutation (SNP) | VAF 26/49 reads (53%) | catalogued as rs150431221; called by muse, mutect2, varscan2
- IPO13 | c.1159C>T p.R387W | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs779126923; called by muse, mutect2, varscan2
- IRX1 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 209/529 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1429660571, COSV100116537, COSV57360506; called by muse, mutect2, varscan2
- IRX4 | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 103/304 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376873295, COSV99180781; called by muse, mutect2, varscan2
- ISM2 | c.1648C>T p.R550* | Nonsense Mutation (SNP) | VAF 68/171 reads (40%) | catalogued as rs1172723498; called by muse, mutect2, varscan2
- ITGA7 | c.2687C>T p.S896L (on ENST00000555728; = p.S852L on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.948); catalogued as rs764412210, COSV57691494; called by muse, varscan2
- ITGAM | c.3011G>A p.R1004H (on ENST00000648685 / NM_001145808.2; = p.R1003H on NM_000632.4) | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs369576245; called by muse, mutect2, varscan2
- ITGB6 | c.2213A>G p.D738G | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1486964947; called by muse, mutect2, varscan2
- ITSN1 | c.2120G>A p.R707Q | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.019); catalogued as rs762453980; called by muse, mutect2, varscan2
- JAG1 | c.1223C>T p.T408M | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773039210, COSV99653189; called by muse, mutect2, varscan2
- JUNB | c.377del p.G126Afs*24 | Frame Shift Del (DEL) | VAF 25/91 reads (27%) | catalogued as rs1425641451; called by mutect2, pindel, varscan2
- KCNH3 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.283); catalogued as rs140606804; called by muse, mutect2, varscan2
- KCNH3 | c.1997C>T p.T666M | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750261167, COSV57790761; called by muse, mutect2, varscan2
- KCNJ5 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs139073333; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNJ9 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 65/221 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV100927826; called by muse, mutect2, varscan2
- KCNT1 | c.2302C>T p.H768Y (on ENST00000488444; = p.H787Y on NM_020822.3) | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1360670404; called by muse, mutect2, varscan2
- KCNV2 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as rs780813722, CM136751; called by muse, mutect2, varscan2
- KCTD15 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV52289817; called by muse, mutect2, varscan2
- KDM4B | c.365A>G p.Y122C | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50245764; called by muse, mutect2, varscan2
- KHDRBS2 | c.641del p.P214Hfs*15 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | catalogued as COSV55440092; called by mutect2, varscan2
- KIAA0232 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 141/378 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs546445842; called by muse, mutect2, varscan2
- KIAA0319 | c.2785C>T p.R929C | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs770931600, COSV65500477; called by muse, mutect2, varscan2
- KIAA1109 | c.8849C>A p.T2950N | Missense Mutation (SNP) | VAF 75/229 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.367); catalogued as COSV52681109; called by muse, mutect2, varscan2
- KIAA1109 | c.10889G>A p.R3630Q | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1019117921, COSV52682924; called by muse, mutect2, varscan2
- KIF21B | c.898C>A p.L300M | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59764909; called by muse, mutect2, varscan2
- KLHDC9 | c.387del p.A130Pfs*37 | Frame Shift Del (DEL) | VAF 21/59 reads (36%) | catalogued as rs761803466; called by mutect2, pindel, varscan2
- KLHL22 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1338267056, COSV61020376; called by muse, mutect2, varscan2
- KLHL34 | c.861del p.R288Afs*7 | Frame Shift Del (DEL) | VAF 99/160 reads (62%) | catalogued as rs762518653; called by mutect2, pindel, varscan2
- KLK1 | c.514C>A p.L172I | Missense Mutation (SNP) | VAF 74/188 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV56827986; called by muse, mutect2, varscan2
- KLRK1 | c.164del p.F55Sfs*7 | Frame Shift Del (DEL) | VAF 48/122 reads (39%) | catalogued as rs756606329, COSV53699502; called by mutect2, varscan2
- KMT2B | c.7216G>A p.A2406T | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV55821706; called by muse, mutect2, varscan2
- KRT32 | c.782T>C p.L261P | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1396304193, COSV56787516; called by muse, mutect2, varscan2
- KRT40 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as rs374397057; called by muse, mutect2, varscan2
- L3MBTL1 | c.2011G>A p.A671T (on ENST00000418998 / NM_001377303.1; = p.A581T on NM_015478.7) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV64229390; called by muse, mutect2, varscan2
- LAMA4 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as rs148801194; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMB1 | c.5125del p.T1709Lfs*22 | Frame Shift Del (DEL) | VAF 85/260 reads (33%) | catalogued as rs1441388757; called by mutect2, pindel, varscan2
- LAMB2 | c.3781G>A p.A1261T | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as CD085819, COSV59736576; called by muse, mutect2, varscan2
- LAMC3 | c.2593C>T p.P865S | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.177); catalogued as rs1394227732, COSV63093963; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 90/262 reads (34%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LATS1 | c.169A>G p.M57V | Missense Mutation (SNP) | VAF 169/421 reads (40%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV53597435; called by muse, mutect2, varscan2
- LHFPL2 | c.497A>G p.Y166C | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.853); catalogued as rs1561300950; called by muse, mutect2, varscan2
- LILRA5 | c.70A>G p.M24V | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs751436611; called by muse, mutect2
- LOXL2 | c.2276del p.K759Sfs*9 | Frame Shift Del (DEL) | VAF 39/155 reads (25%) | catalogued as rs765428971; called by mutect2, pindel, varscan2
- LPIN3 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs780659323, COSV64717503; called by muse, mutect2, varscan2
- LRP2 | c.10646C>T p.P3549L | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs199806925; called by muse, mutect2, varscan2
- LRP5 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1332274863; called by muse, mutect2, varscan2
- LRRTM2 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757429405, COSV51220797; called by muse, mutect2, varscan2
- LUM | c.49A>G p.S17G | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs200635075; called by muse, mutect2, varscan2
- LZTS2 | c.68C>A p.A23D | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.08); catalogued as COSV64652490; called by muse, mutect2, varscan2
- MACIR | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated, low confidence (0.59); PolyPhen possibly damaging (0.725); catalogued as rs782593060, COSV60635675; called by muse, mutect2, varscan2
- MAEA | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 92/259 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs758614928, COSV53262311, COSV53263603; called by muse, mutect2, varscan2
- MAP3K8 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.764); catalogued as rs532844555, COSV53920720; called by muse, mutect2, varscan2
- MAPK3 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764219989; called by muse, mutect2, varscan2
- MAT2B | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 66/202 reads (33%) | catalogued as COSV99797043; called by muse, mutect2, varscan2
- MBD1 | c.1508C>T p.A503V (on ENST00000269468 / NM_001323950.1; = p.A447V on NM_015844.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs555450900, COSV53999572; called by muse, mutect2, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 98/376 reads (26%) | catalogued as rs1180255648; called by pindel, varscan2
- MEGF6 | c.3125G>A p.C1042Y | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53894353; called by muse, mutect2, varscan2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 26/102 reads (25%) | catalogued as rs762115034; called by mutect2, pindel, varscan2
- MEST | c.64G>A p.V22M | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs781957359, COSV56229621; called by muse, mutect2, varscan2
- METAP1 | c.644A>G p.D215G | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56445492; called by muse, mutect2, varscan2
- METTL15 | c.523A>G p.M175V | Missense Mutation (SNP) | VAF 93/319 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs753752723; called by muse, mutect2, varscan2
- METTL27 | c.718C>T p.R240* | Nonsense Mutation (SNP) | VAF 33/109 reads (30%) | catalogued as rs556800237; called by muse, mutect2, varscan2
- MICAL2 | c.3082C>T p.R1028C | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs751050743, COSV99816915; called by muse, mutect2, varscan2
- MICOS13 | c.150del p.A51Pfs*39 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | catalogued as rs751944867; called by mutect2, pindel, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 52/76 reads (68%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MMEL1 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 134/355 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.906); catalogued as rs568619305, COSV99984185; called by muse, mutect2, varscan2
- MMRN1 | c.2646del p.G883Afs*3 | Frame Shift Del (DEL) | VAF 63/216 reads (29%) | catalogued as rs750319971; called by mutect2, pindel, varscan2
- MN1 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.866); catalogued as rs773965619; called by muse, varscan2
- MNDA | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 124/337 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.92); catalogued as COSV63740650; called by muse, mutect2, varscan2
- MOG | c.216dup p.F73Lfs*3 | Frame Shift Ins (INS) | VAF 54/144 reads (38%) | catalogued as rs761971886; called by mutect2, varscan2
- MPO | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1481343975; called by muse, mutect2, varscan2
- MRNIP | c.590A>G p.Q197R | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs773459500, COSV52974806; called by muse, mutect2, varscan2
- MRPS22 | c.757_760del p.D253Nfs*22 (on ENST00000310776 / NM_001363893.1; = p.D254Nfs*22 on NM_020191.4) | Frame Shift Del (DEL) | VAF 51/127 reads (40%) | catalogued as rs868695898; called by mutect2, pindel, varscan2
- MUC16 | c.11234C>A p.S3745* | Nonsense Mutation (SNP) | VAF 74/178 reads (42%) | catalogued as COSV101197258; called by muse, mutect2, varscan2
- MYH1 | c.4996C>T p.R1666W | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs773071362, COSV56844808; called by muse, mutect2, varscan2
- MYH13 | c.1364G>A p.R455K | Missense Mutation (SNP) | VAF 129/370 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV52838645; called by muse, mutect2, varscan2
- MYO1C | c.2438G>A p.R813H (on ENST00000648651 / NM_001080779.2; = p.R778H on NM_033375.5) | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs377675305; called by muse, mutect2, varscan2
- MYO1E | c.2761G>A p.G921R | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs778885841; called by muse, mutect2, varscan2
- MYOF | c.5151C>G p.H1717Q | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as rs750862119; called by muse, mutect2, varscan2
- MYOM2 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs148337899; called by muse, mutect2, varscan2
- MYPOP | c.1139del p.P380Hfs*26 | Frame Shift Del (DEL) | VAF 24/99 reads (24%) | catalogued as rs757587344; called by mutect2, pindel, varscan2
- N4BP2L2 | c.1496T>C p.V499A | Missense Mutation (SNP) | VAF 114/347 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV57229556; called by muse, mutect2, varscan2
- NAT10 | c.2776A>G p.M926V | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1391360080; called by muse, varscan2
- NDN | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as rs1243771358; called by muse, mutect2, varscan2
- NEDD4 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.084); catalogued as COSV59058813; called by muse, mutect2, varscan2
- NEFM | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV55335457; called by muse, mutect2, varscan2
- NEK11 | c.1398T>C p.H466= | Splice Region (SNP) | VAF 89/251 reads (35%) | catalogued as rs898393652; called by muse, mutect2, varscan2
- NEK4 | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 142/394 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99238217; called by muse, mutect2, varscan2
- NETO1 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.83); catalogued as COSV55011102; called by muse, mutect2, varscan2
- NEUROD4 | c.624del p.L209Ffs*49 | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | catalogued as COSV54470431; called by mutect2, pindel, varscan2
- NFASC | c.3226C>T p.R1076W | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs370375266; called by muse, mutect2, varscan2
- NFATC1 | c.2497A>G p.S833G (on ENST00000427363 / NM_001278669.2; = p.S820G on NM_172387.3) | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV53706853; called by muse, mutect2, varscan2
- NFRKB | c.932del p.K311Rfs*13 (on ENST00000446488 / NM_001143835.2; = p.K336Rfs*13 on NM_006165.3) | Frame Shift Del (DEL) | VAF 28/70 reads (40%) | catalogued as rs149369172, COSV58756820; called by mutect2, varscan2
- NKX2-2 | c.370del p.D124Tfs*60 | Frame Shift Del (DEL) | VAF 37/105 reads (35%) | catalogued as rs752776917; called by mutect2, pindel, varscan2
- NLRC3 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.539); catalogued as rs767898156, COSV57094345; called by muse, mutect2, varscan2
- NLRP7 | c.928C>A p.Q310K | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.183); catalogued as COSV60179556; called by muse, mutect2, varscan2
- NOL4 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as rs1489837297; called by muse, mutect2, varscan2
- NOS1 | c.2015G>A p.R672H | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs764344401, COSV100500499, COSV57611683, COSV57620123; called by muse, mutect2, varscan2
- NOTCH4 | c.1159G>T p.G387* | Nonsense Mutation (SNP) | VAF 25/58 reads (43%) | catalogued as COSV66679028; called by muse, mutect2, varscan2
- NPM2 | c.194T>G p.L65R | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV57076384; called by muse, mutect2, varscan2
- NPPB | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.725); catalogued as rs377083056, COSV64687495; called by muse, mutect2, varscan2
- NSL1 | c.808T>C p.Y270H | Missense Mutation (SNP) | VAF 88/231 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65329793; called by muse, mutect2, varscan2
- NTNG1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.307); catalogued as COSV53972123; called by muse, mutect2, varscan2
- NUB1 | c.946T>G p.F316V | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.06); catalogued as COSV100879428; called by muse, mutect2, varscan2
- OAF | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.036); catalogued as rs773363476; called by muse, mutect2, varscan2
- OCA2 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.086); catalogued as rs370353320; called by muse, mutect2, varscan2
- ODF3L2 | c.646C>A p.R216S | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.133); catalogued as COSV52748627; called by muse, mutect2, varscan2
- OPLAH | c.2161G>A p.V721M | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.882); catalogued as rs782158791, COSV70677850; called by muse, mutect2, varscan2
- OPN4 | c.781G>T p.A261S | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.773); catalogued as COSV54118504; called by muse, mutect2, varscan2
- OPRK1 | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.03); catalogued as rs200159306, COSV55568063; called by muse, mutect2, varscan2
- OR13C8 | c.322G>T p.G108W | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58610926; called by muse, mutect2, varscan2
- OR14I1 | c.448T>C p.C150R | Missense Mutation (SNP) | VAF 85/237 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV61200533; called by muse, mutect2, varscan2
- OR2S2 | c.906G>T p.K302N | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV59530895; called by muse, mutect2, varscan2
- OR2T4 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 224/600 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as rs199743254, COSV63544206, COSV63544524; called by muse, mutect2, varscan2
- OR4B1 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 132/346 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs149306992; called by muse, varscan2
- OR6C70 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as rs1199369365, COSV59244938; called by muse, mutect2, varscan2
- OR7E24 | c.955C>A p.L319M | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as COSV71702316; called by muse, mutect2, varscan2
- OR7G2 | c.233C>T p.T78I | Missense Mutation (SNP) | VAF 73/173 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.331); catalogued as COSV59688683; called by muse, mutect2, varscan2
- OR8G1 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.078); catalogued as rs1364839329; called by muse, mutect2, varscan2
- OVCH1 | c.2102C>G p.T701S | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.866); catalogued as COSV58967160; called by muse, mutect2, varscan2
- PABPC3 | c.1063G>A p.G355S | Missense Mutation (SNP) | VAF 106/392 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as rs747031541, COSV55798558; called by muse, varscan2
- PACSIN3 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs146380567; called by muse, mutect2, varscan2
- PAK4 | c.565del p.Q189Sfs*180 | Frame Shift Del (DEL) | VAF 53/109 reads (49%) | catalogued as rs1217359611; called by mutect2, pindel, varscan2
- PALLD | c.2609C>A p.A870D (on ENST00000505667 / NM_001166108.2; = p.A853D on NM_016081.4) | Missense Mutation (SNP) | VAF 69/232 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54990804; called by muse, mutect2, varscan2
- PAQR3 | c.23G>A p.S8N | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV55011323; called by muse, mutect2, varscan2
- PARP6 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as rs769021644; called by muse, mutect2, varscan2
- PCDH10 | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52099108, COSV99993103; called by muse, mutect2, varscan2
- PCDH10 | c.3080C>T p.A1027V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.062); catalogued as COSV52097431; called by muse, mutect2, varscan2
- PCDHA10 | c.1540G>A p.G514S | Missense Mutation (SNP) | VAF 163/353 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100254230; called by muse, mutect2, varscan2
- PCDHA2 | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 101/280 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV65364430; called by mutect2, varscan2
- PCDHGA5 | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.021); catalogued as COSV53947180; called by muse, mutect2, varscan2
- PCLO | c.10778C>A p.P3593Q | Missense Mutation (SNP) | VAF 75/236 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); catalogued as COSV61657332; called by muse, mutect2, varscan2
- PCM1 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 72/170 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.034); catalogued as rs1387173208; called by muse, varscan2
- PCSK5 | c.4820A>G p.H1607R | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.152); catalogued as rs756647719; called by muse, mutect2, varscan2
- PDE2A | c.2267G>A p.R756H | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs759387435, COSV57804265; called by muse, mutect2, varscan2
- PDLIM7 | c.310T>A p.Y104N | Missense Mutation (SNP) | VAF 95/228 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.171); catalogued as COSV62883685; called by muse, mutect2, varscan2
- PDS5A | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 27/69 reads (39%) | catalogued as COSV57823430; called by muse, varscan2
- PDS5A | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 102/291 reads (35%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.835); catalogued as rs1328959525; called by muse, varscan2
- PFKL | c.2200C>T p.R734C | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1453469320, COSV57394726; called by muse, mutect2, varscan2
- PHF20L1 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55190658; called by muse, mutect2, varscan2
- PHLDB1 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.148); catalogued as rs369034044; called by muse, mutect2, varscan2
- PHLDB1 | c.3418G>A p.A1140T | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs137998974; called by muse, mutect2, varscan2
- PIP5K1C | c.1979del p.P660Rfs*225 | Frame Shift Del (DEL) | VAF 14/69 reads (20%) | catalogued as rs748532409; called by mutect2, pindel, varscan2
- PKN3 | c.2036_2038del p.K679del | In Frame Del (DEL) | VAF 98/346 reads (28%) | catalogued as rs747170999; called by pindel, varscan2
- PKP3 | c.565G>A p.G189R | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs554635370, COSV58988399; called by muse, mutect2, varscan2
- PLAT | c.212G>A p.C71Y | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99535514; called by muse, mutect2, varscan2
- PLCB3 | c.1093G>A p.V365M | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV54188479; called by muse, mutect2, varscan2
- PLCD3 | c.1509G>T p.E503D | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1422702300, COSV59560156; called by muse, mutect2, varscan2
- PLCG1 | c.2602del p.L868* | Frame Shift Del (DEL) | VAF 88/285 reads (31%) | catalogued as COSV54822506; called by mutect2, pindel, varscan2
- POLM | c.290del p.P97Qfs*6 | Frame Shift Del (DEL) | VAF 32/98 reads (33%) | catalogued as rs745933237; called by mutect2, pindel, varscan2
- POLR2J | c.250del p.Q84Rfs*26 | Frame Shift Del (DEL) | VAF 218/1144 reads (19%) | catalogued as rs779046727; called by pindel, varscan2
- PPP1CC | c.431A>G p.Y144C | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV58584692; called by muse, varscan2
- PPP5C | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50143747; called by muse, mutect2
- PRKCSH | c.14T>C p.L5P | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs767980900, COSV99371622; called by muse, mutect2, varscan2
- PROCR | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746777605, COSV99405830; called by muse, mutect2, varscan2
- PRPH | c.609C>T p.D203= | Splice Region (SNP) | VAF 21/65 reads (32%) | catalogued as rs746174471, COSV57679493; called by muse, mutect2, varscan2
- PRR12 | c.37dup p.H13Pfs*103 (on ENST00000615927; = p.P409Tfs*150 on NM_020719.3) | Frame Shift Ins (INS) | VAF 58/152 reads (38%) | catalogued as rs763575972; called by mutect2, varscan2
- PRSS37 | c.643G>A p.V215I | Missense Mutation (SNP) | VAF 77/224 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.13); catalogued as rs745313899, COSV63339390; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTK2B | c.1032G>T p.M344I | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.083); catalogued as COSV57763433; called by muse, mutect2, varscan2
- PTPRG | c.3629A>G p.Y1210C | Missense Mutation (SNP) | VAF 103/251 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375459395; called by muse, mutect2, varscan2
- PTPRS | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as rs760369713; called by muse, mutect2, varscan2
- PVRIG | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as rs374498791; called by muse, mutect2, varscan2
- PYGM | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.891); catalogued as rs567482511; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- QRICH1 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as rs76308243; called by muse, mutect2, varscan2
- RAB21 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54229818; called by muse, mutect2, varscan2
- RADIL | c.2642del p.P881Lfs*110 | Frame Shift Del (DEL) | VAF 31/118 reads (26%) | catalogued as rs767679528; called by mutect2, pindel, varscan2
- RALGAPA2 | c.2754del p.S919Afs*24 | Frame Shift Del (DEL) | VAF 23/86 reads (27%) | catalogued as COSV99173620; called by mutect2, pindel, varscan2
- RAPGEF1 | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as COSV64701224; called by muse, mutect2, varscan2
- RASAL1 | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs777154983; called by muse, mutect2, varscan2
- RBP3 | c.265A>G p.I89V | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.881); catalogued as rs782765523; called by muse, mutect2, varscan2
- RBP4 | c.71T>C p.V24A | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65160605; called by muse, mutect2, varscan2
- RETN | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 93/218 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs1204846568; called by muse, mutect2, varscan2
- RIMS1 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 114/319 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1044390019, COSV53488608; called by muse, mutect2, varscan2
- RIOX2 | c.87del p.P30Lfs*4 | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | catalogued as rs759850891; called by mutect2, pindel, varscan2
- RNF182 | c.301C>A p.L101M | Missense Mutation (SNP) | VAF 69/170 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.193); catalogued as COSV70369847; called by muse, mutect2, varscan2
- ROBO1 | c.85C>A p.P29T | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV71972350; called by muse, mutect2, varscan2
- ROCK2 | c.2333T>C p.L778P | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59962931; called by muse, mutect2, varscan2
- RORC | c.830T>C p.V277A | Missense Mutation (SNP) | VAF 74/178 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV59094869; called by muse, varscan2
- RPA1 | c.541C>G p.Q181E | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.95); PolyPhen benign (0.055); catalogued as rs1426220623; called by muse, mutect2, varscan2
- RPS6KA1 | c.1907T>C p.L636P | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV65177468; called by muse, mutect2, varscan2
- RTN4RL1 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs755513471; called by muse, mutect2, varscan2
- RUSC2 | c.1753del p.A585Pfs*62 | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | catalogued as COSV100771001; called by mutect2, pindel, varscan2
- RYR1 | c.8281T>C p.Y2761H | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as rs1036696718; called by muse, mutect2, varscan2
- SATB1 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV58671870; called by muse, mutect2, varscan2
- SBF1 | c.1838G>A p.R613H | Missense Mutation (SNP) | VAF 137/387 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as rs754441426, COSV62371078; called by muse, mutect2, varscan2
- SCAF1 | c.3845G>A p.R1282H | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs760624103; called by muse, mutect2, varscan2
- SCN11A | c.2169del p.F723Lfs*37 | Frame Shift Del (DEL) | VAF 93/288 reads (32%) | catalogued as rs1559515942, COSV56576505; called by mutect2, pindel, varscan2
- SDK1 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs202020244; called by muse, mutect2, varscan2
- SDK1 | c.6472C>T p.R2158C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773023013; called by muse, mutect2, varscan2
- SEC61A1 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 71/179 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV54577633; called by muse, mutect2, varscan2
- SEMA4A | c.338G>A p.C113Y | Missense Mutation (SNP) | VAF 136/341 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61773632; called by muse, mutect2, varscan2
- SENP6 | c.2079C>A p.Y693* | Nonsense Mutation (SNP) | VAF 59/189 reads (31%) | catalogued as COSV64189584; called by muse, mutect2, varscan2
- SGPL1 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1437439236, COSV64592260; called by muse, mutect2, varscan2
- SH2D5 | c.661C>T p.R221C (on ENST00000444387 / NM_001103161.2; = p.R137C on NM_001103160.2) | Missense Mutation (SNP) | VAF 64/252 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.984); catalogued as rs369171247; called by muse, mutect2, varscan2
- SHTN1 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776059035, COSV53386180; called by muse, mutect2, varscan2
- SIGLEC1 | c.3140_3141insA p.N1048Qfs*15 | Frame Shift Ins (INS) | VAF 46/136 reads (34%) | catalogued as COSV52469961; called by mutect2, pindel, varscan2
- SIK3 | c.3898A>G p.M1300V (on ENST00000445177 / NM_001366686.2; = p.M1258V on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/205 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs150218961; called by muse, mutect2, varscan2
- SLC10A6 | c.326del p.G109Afs*21 | Frame Shift Del (DEL) | VAF 48/144 reads (33%) | catalogued as rs753933531, COSV56721805; called by mutect2, pindel, varscan2
- SLC13A5 | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs1022127944; called by muse, mutect2, varscan2
- SLC17A1 | c.33del p.V12Ffs*21 | Frame Shift Del (DEL) | VAF 38/138 reads (28%) | catalogued as rs772930118, COSV55082252; called by mutect2, pindel, varscan2
- SLC22A14 | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 101/242 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756499375, COSV56199040; called by muse, mutect2, varscan2
- SLC22A7 | c.1238C>T p.T413M (on ENST00000372585 / NM_153320.2; = p.T411M on NM_006672.3) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs776077806, COSV51482649; called by muse, mutect2, varscan2
- SLC22A7 | c.1504G>T p.A502S (on ENST00000372585 / NM_153320.2; = p.A500S on NM_006672.3) | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.376); catalogued as COSV51482725; called by muse, mutect2, varscan2
- SLC26A3 | c.1261G>A p.V421M | Missense Mutation (SNP) | VAF 74/187 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1415789229, COSV60641954; called by muse, mutect2, varscan2
- SLC26A4 | c.2131G>A p.D711N | Missense Mutation (SNP) | VAF 84/236 reads (36%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.904); catalogued as rs145805875, COSV55917059; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC34A3 | c.1207A>G p.M403V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs771932709; called by muse, mutect2, varscan2
- SLC4A1 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as rs56312419; called by muse, mutect2, varscan2
- SLC4A3 | c.2652del p.S885Afs*22 | Frame Shift Del (DEL) | VAF 134/442 reads (30%) | catalogued as rs760972612; called by mutect2, pindel, varscan2
- SLC5A10 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs551200304; called by muse, mutect2, varscan2
- SLC6A1 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1391625316, COSV55116446; called by muse, mutect2, varscan2
- SLC6A3 | c.1639dup p.H547Pfs*56 | Frame Shift Ins (INS) | VAF 34/96 reads (35%) | catalogued as rs749320240; called by mutect2, varscan2
- SLC7A5 | c.1480G>A p.V494I | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs200265403; called by muse, mutect2, varscan2
- SLIT1 | c.3665G>A p.R1222H | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs780115071, COSV99820503; called by muse, mutect2, varscan2
- SMARCAL1 | c.1465G>A p.V489M | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as rs745494010; called by muse, mutect2, varscan2
- SMPX | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 80/119 reads (67%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.061); catalogued as rs746359009, COSV65277225; called by muse, mutect2, varscan2
- SNRNP35 | c.443del p.K148Rfs*6 | Frame Shift Del (DEL) | VAF 25/69 reads (36%) | catalogued as rs1566105559; called by mutect2, pindel, varscan2
- SOBP | c.2554G>A p.A852T | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV100432945; called by muse, mutect2, varscan2
- SOHLH2 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 83/224 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs144696055, COSV65903471, COSV65904086; called by muse, mutect2, varscan2
- SORBS2 | c.1837C>A p.L613I | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV99511638; called by muse, mutect2, varscan2
- SPARC | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370328004; called by muse, mutect2, varscan2
- SPDEF | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV55061910; called by muse, mutect2, varscan2
- SPEG | c.8129C>T p.T2710M | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs865794814, COSV56663107; called by muse, mutect2, varscan2
- SPEN | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1460194680, COSV65369666; called by muse, mutect2, varscan2
- SPINK5 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs774354593, COSV56253349; called by muse, mutect2, varscan2
- SPIRE2 | c.1578G>C p.E526D | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV65557108; called by muse, mutect2, varscan2
- SPOCK1 | c.1258G>A p.V420M | Missense Mutation (SNP) | VAF 114/329 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.101); catalogued as rs569345414, COSV56435804; called by muse, varscan2
- SRL | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as rs1252715774, COSV68424101; called by muse, mutect2, varscan2
- ST8SIA4 | c.680C>A p.A227D | Missense Mutation (SNP) | VAF 50/174 reads (29%) | PolyPhen possibly damaging (0.658); catalogued as COSV99185323; called by muse, mutect2, varscan2
- STAT5A | c.1681-2A>G p.X561_splice | Splice Site (SNP) | VAF 36/104 reads (35%) | catalogued as COSV61807961; called by muse, mutect2, varscan2
- STOX1 | c.1994A>G p.Q665R | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); catalogued as rs774996884; called by muse, mutect2, varscan2
- SUCO | c.3616C>T p.R1206* | Nonsense Mutation (SNP) | VAF 61/167 reads (37%) | catalogued as rs1280900260; called by muse, mutect2, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 93/287 reads (32%) | catalogued as rs770033147; called by mutect2, pindel, varscan2
- SYN3 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs745749577, COSV60511988; called by muse, mutect2, varscan2
- TAF3 | c.1016C>T p.T339M | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.572); catalogued as rs753695849; called by muse, mutect2, varscan2
- TAS2R30 | c.385G>T p.V129F | Missense Mutation (SNP) | VAF 83/246 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as rs756309845; called by muse, mutect2, varscan2
- TBC1D4 | c.2423T>C p.L808P | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV66487541; called by muse, mutect2
- TBC1D5 | c.1168G>T p.G390C | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV53760577; called by muse, mutect2, varscan2
- TBX10 | c.291del p.F98Sfs*3 | Frame Shift Del (DEL) | VAF 23/93 reads (25%) | catalogued as rs748952707, COSV56876494; called by mutect2, varscan2
- TCF12 | c.1035+1G>T p.X345_splice | Splice Site (SNP) | VAF 35/87 reads (40%) | catalogued as COSV51003339; called by muse, mutect2, varscan2
- TENM3 | c.4799C>T p.A1600V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV69302498; called by muse, mutect2, varscan2
- TENM4 | c.3898C>T p.R1300W | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1026919229, COSV53640237; called by muse, mutect2, varscan2
- TEX35 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.125); catalogued as COSV99274850; called by muse, mutect2, varscan2
- TFPI | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.101); catalogued as rs568113767, COSV51903902, COSV51906042; called by muse, mutect2, varscan2
- TGFBR2 | c.212G>A p.C71Y | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55444459; called by muse, mutect2, varscan2
- THBS2 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as rs577676627, COSV64681307; called by muse, mutect2, varscan2
- TICRR | c.3858T>A p.D1286E | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs778370830; called by muse, mutect2, varscan2
- TIGD3 | c.588G>T p.Q196H | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.683); catalogued as COSV52890885; called by muse, mutect2, varscan2
- TIGD6 | c.979C>T p.Q327* | Nonsense Mutation (SNP) | VAF 99/275 reads (36%) | catalogued as rs765139318; called by muse, mutect2, varscan2
- TJP1 | c.3067G>A p.A1023T | Missense Mutation (SNP) | VAF 69/238 reads (29%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV100633191; called by muse, mutect2, varscan2
- TJP1 | c.1348G>A p.V450I | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as rs1304157065, COSV100632885; called by muse, mutect2, varscan2
- TLE4 | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54629718; called by muse, mutect2, varscan2
- TLN2 | c.2579T>G p.L860R | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1299563860; called by muse, mutect2, varscan2
- TMEM161B | c.229A>G p.I77V | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1445507972; called by muse, mutect2, varscan2
- TMEM64 | c.943dup p.C315Lfs*30 | Frame Shift Ins (INS) | VAF 12/27 reads (44%) | catalogued as rs1563955623; called by mutect2, pindel, varscan2
- TMEM64 | c.771del p.F257Lfs*19 | Frame Shift Del (DEL) | VAF 40/126 reads (32%) | catalogued as COSV69128187; called by mutect2, pindel, varscan2
- TMEM8B | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs969693098, COSV65076800; called by muse, mutect2, varscan2
- TMEM94 | c.2682del p.S895Pfs*13 | Frame Shift Del (DEL) | VAF 28/80 reads (35%) | catalogued as rs747222326; called by mutect2, pindel, varscan2
- TMPRSS11D | c.1033G>A p.G345R | Missense Mutation (SNP) | VAF 106/309 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52221805; called by muse, mutect2, varscan2
- TNKS | c.350C>A p.A117D | Missense Mutation (SNP) | VAF 145/391 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.051); catalogued as rs963339036; called by muse, mutect2, varscan2
- TNR | c.2260G>A p.V754I | Missense Mutation (SNP) | VAF 88/261 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs370853708; called by muse, mutect2, varscan2
- TPD52L1 | c.590C>T p.T197I | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); catalogued as rs1432886849, COSV59193292; called by muse, mutect2, varscan2
- TPM3 | c.642+2T>C p.X214_splice (on ENST00000368530 / NM_001364682.1; = p.X177_splice on NM_153649.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 34/86 reads (40%) | catalogued as COSV55138476; called by muse, mutect2, varscan2
- TPMT | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV59429778; called by muse, mutect2, varscan2
- TRAP1 | c.1198C>A p.L400I | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV55915164; called by muse, mutect2, varscan2
- TRIM3 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV61983326; called by muse, mutect2, varscan2
- TRIM46 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.97); catalogued as rs764327631; called by muse, mutect2, varscan2
- TRIM47 | c.1312_1314del p.D438del | In Frame Del (DEL) | VAF 26/100 reads (26%) | catalogued as COSV54669219; called by mutect2, pindel, varscan2
- TRIM54 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.416); catalogued as rs770394298, COSV56083101; called by muse, mutect2
- TRIM69 | c.1040A>G p.H347R (on ENST00000329464 / NM_182985.5; = p.H188R on NM_080745.5) | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV57804965; called by muse, mutect2, varscan2
- TRMT10A | c.322A>G p.S108G | Missense Mutation (SNP) | VAF 133/345 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs892092755; called by muse, mutect2, varscan2
- TRMT10B | c.111G>T p.Q37H | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); catalogued as rs370222676, COSV53049623; called by muse, mutect2, varscan2
- TRPM2 | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 57/196 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs559271467, COSV55975122; called by muse, mutect2, varscan2
- TRPM4 | c.679T>G p.Y227D | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.387); catalogued as COSV53265436; called by muse, mutect2, varscan2
- TSBP1 | c.670del p.S224Lfs*8 (on ENST00000617061; = p.S227Lfs*8 on NM_006781.5) | Frame Shift Del (DEL) | VAF 69/255 reads (27%) | catalogued as COSV66660771; called by mutect2, varscan2
- TSPAN10 | c.456del p.L154Cfs*19 (on ENST00000574882 / NM_001290212.1; = p.L116Cfs*19 on NM_031945.4) | Frame Shift Del (DEL) | VAF 32/99 reads (32%) | catalogued as rs771262491, COSV100148738, COSV60773593; called by mutect2, pindel, varscan2
- TTC17 | c.2398C>T p.R800W | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs369116264; called by muse, mutect2, varscan2
- TTK | c.2571del p.K857Nfs*36 | Frame Shift Del (DEL) | VAF 34/259 reads (13%) | catalogued as rs768996038, COSV57882295; called by pindel, varscan2
- TTN | c.101954del p.L33985* (on ENST00000591111; = p.L26561* on NM_003319.4) | Frame Shift Del (DEL) | VAF 97/406 reads (24%) | catalogued as COSV60210267; called by mutect2, pindel, varscan2
- TTN | c.89229T>G p.S29743R (on ENST00000591111; = p.S22319R on NM_003319.4) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | PolyPhen possibly damaging (0.447); catalogued as COSV100620413; called by muse, mutect2, varscan2
- TTN | c.44920C>T p.L14974F (on ENST00000591111; = p.L7550F on NM_003319.4) | Missense Mutation (SNP) | VAF 31/89 reads (35%) | PolyPhen probably damaging (0.999); catalogued as rs1212016273; called by muse, mutect2, varscan2
- TTN | c.29071A>G p.M9691V (on ENST00000591111; = p.M8764V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/173 reads (35%) | PolyPhen benign (0.023); catalogued as rs1553877757; ClinVar: likely benign; called by muse, mutect2, varscan2
- TUBA3E | c.5G>T p.R2L | Missense Mutation (SNP) | VAF 92/300 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as COSV57270960; called by muse, mutect2, varscan2
- TUBB8 | c.935C>T p.T312M | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.698); catalogued as rs559882106, COSV59115129; called by muse, mutect2, varscan2
- TUFT1 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs908874712; called by muse, varscan2
- TULP1 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV57693561, COSV57693652; called by muse, mutect2, varscan2
- TUT4 | c.2213C>T p.S738L | Missense Mutation (SNP) | VAF 89/304 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs749101927; called by muse, mutect2, varscan2
- UBE2C | c.500A>G p.Q167R | Missense Mutation (SNP) | VAF 62/208 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs1029457888; called by muse, mutect2, varscan2
- UNC80 | c.373del p.Q125Rfs*109 | Frame Shift Del (DEL) | VAF 24/69 reads (35%) | catalogued as rs1479980338; called by mutect2, pindel, varscan2
- USP34 | c.603T>C p.N201= | Splice Region (SNP) | VAF 77/244 reads (32%) | catalogued as rs1470313525; called by muse, mutect2, varscan2
- USP4 | c.896C>A p.P299H | Missense Mutation (SNP) | VAF 15/336 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99649470; called by muse, mutect2
- USP4 | c.836+1del p.X279_splice | Splice Site (DEL) | VAF 63/181 reads (35%) | catalogued as rs1438089939; called by mutect2, pindel, varscan2
- UST | c.242A>G p.Y81C | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); catalogued as rs747844853; called by muse, mutect2, varscan2
- UTRN | c.8140C>T p.R2714W | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs778217389; called by muse, mutect2, varscan2
- UTS2R | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs201087931; called by muse, mutect2, varscan2
- VASH1 | c.12del p.K5Rfs*146 | Frame Shift Del (DEL) | VAF 27/84 reads (32%) | catalogued as rs1566680298, COSV99387951; called by mutect2, pindel, varscan2
- VIPR2 | c.287A>G p.D96G | Missense Mutation (SNP) | VAF 76/233 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as rs1380792061; called by muse, mutect2, varscan2
- VPS51 | c.1749G>T p.Q583H | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54208962; called by muse, mutect2, varscan2
- WASF3 | c.1367del p.K456Rfs*61 | Frame Shift Del (DEL) | VAF 60/163 reads (37%) | catalogued as COSV58963930; called by mutect2, pindel, varscan2
- WBP1 | c.552del p.H185Ifs*10 | Frame Shift Del (DEL) | VAF 109/358 reads (30%) | catalogued as rs773064295, COSV51967888; called by mutect2, pindel, varscan2
- WDR81 | c.4367C>A p.P1456Q (on ENST00000409644 / NM_001163809.2; = p.P405Q on NM_152348.4) | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.037); catalogued as rs749340184; called by muse, mutect2, varscan2
- WIZ | c.5615del p.P1872Hfs*152 (on ENST00000673675 / NM_001371589.1; = p.P777Hfs*152 on NM_021241.3) | Frame Shift Del (DEL) | VAF 22/88 reads (25%) | catalogued as rs1387099118; called by mutect2, pindel, varscan2
- WNT1 | c.506del p.G169Afs*30 | Frame Shift Del (DEL) | VAF 43/128 reads (34%) | catalogued as COSV53295493; called by mutect2, pindel, varscan2
- WWC2 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV66715733; called by muse, mutect2, varscan2
- YBX3 | c.629del p.P210Lfs*58 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | catalogued as rs1051287909; called by pindel, varscan2
- ZAP70 | c.1482+1G>A p.X494_splice | Splice Site (SNP) | VAF 28/56 reads (50%) | catalogued as rs1408769397; called by muse, mutect2, varscan2
- ZBTB2 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.025); catalogued as rs762417728, COSV100287639; called by muse, mutect2, varscan2
- ZBTB24 | c.1190A>G p.Y397C | Missense Mutation (SNP) | VAF 127/353 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV57782878; called by muse, mutect2, varscan2
- ZC3H12A | c.737A>G p.Y246C | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100897775; called by muse, mutect2, varscan2
- ZC3H7B | c.2800C>T p.R934C | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs1356461057; called by muse, varscan2
- ZCCHC14 | c.1787T>C p.V596A (on ENST00000268616; = p.V733A on NM_015144.3) | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.97); catalogued as COSV51891341; called by muse, mutect2, varscan2
- ZFPM2 | c.706A>G p.M236V | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV65875272; called by muse, mutect2, varscan2
- ZGRF1 | c.2312dup p.H772Afs*13 | Frame Shift Ins (INS) | VAF 49/167 reads (29%) | catalogued as rs772299653; called by mutect2, pindel, varscan2
- ZHX2 | c.770A>C p.K257T | Missense Mutation (SNP) | VAF 77/206 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV58710141; called by muse, mutect2, varscan2
- ZHX2 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs375789703; called by muse, mutect2, varscan2
- ZMIZ1 | c.2243G>A p.R748H | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1345500965, COSV100566586; called by muse, mutect2, varscan2
- ZNF331 | c.1247del p.C416Lfs*36 | Frame Shift Del (DEL) | VAF 40/145 reads (28%) | catalogued as COSV53479042; called by mutect2, pindel, varscan2
- ZNF382 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.661); catalogued as rs757614823, COSV53089979; called by muse, mutect2, varscan2
- ZNF483 | c.1228A>C p.T410P | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100492952; called by muse, mutect2, varscan2
- ZNF496 | c.1736G>A p.R579H | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs1384081716, COSV54175748, COSV99665423; called by muse, mutect2, varscan2
- ZNF524 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs774601573; called by muse, varscan2
- ZNF524 | c.214del p.V72* | Frame Shift Del (DEL) | VAF 19/55 reads (35%) | catalogued as rs1249713061; called by pindel, varscan2
- ZNF529 | c.1348T>C p.Y450H | Missense Mutation (SNP) | VAF 79/188 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as rs770236184, COSV61901598; called by muse, mutect2, varscan2
- ZNF540 | c.843del p.F281Lfs*4 | Frame Shift Del (DEL) | VAF 16/65 reads (25%) | catalogued as rs757107073, COSV57110076; called by mutect2, pindel, varscan2
- ZNF600 | c.626G>A p.C209Y | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs577242932, COSV100592864; called by muse, mutect2, varscan2
- ZNF611 | c.1883G>A p.G628D | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.133); catalogued as rs773897099; called by muse, varscan2
- ZNF615 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 68/191 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs368939031; called by muse, mutect2, varscan2
- ZNF638 | c.4769G>A p.R1590H | Missense Mutation (SNP) | VAF 72/174 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs149013084; called by muse, mutect2, varscan2
- ZNF648 | c.1390G>A p.V464M | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV60573111; called by muse, mutect2, varscan2
- ZNF667 | c.1403A>G p.E468G | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs763602581, COSV52633929; called by muse, mutect2, varscan2
- ZNF791 | c.1707dup p.H570Tfs*12 | Frame Shift Ins (INS) | VAF 40/158 reads (25%) | catalogued as rs781098128; called by mutect2, varscan2
- A3GALT2 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- ABCA6 | c.4736A>G p.Q1579R | Missense Mutation (SNP) | VAF 88/251 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ABCA6 | c.1631dup p.N544Kfs*4 | Frame Shift Ins (INS) | VAF 25/80 reads (31%) | called by mutect2, pindel, varscan2
- ABCC10 | c.4213A>G p.I1405V (on ENST00000372530 / NM_001198934.2; = p.I1377V on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- ABCG4 | c.458T>C p.L153P | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ABHD13 | c.910T>C p.C304R | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- AC244197.3 | c.503C>G p.P168R | Missense Mutation (SNP) | VAF 100/166 reads (60%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ACAA1 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ACTR6 | c.942del p.F314Lfs*6 | Frame Shift Del (DEL) | VAF 38/136 reads (28%) | called by mutect2, pindel, varscan2
- ACTR8 | c.775del p.S259Qfs*18 | Frame Shift Del (DEL) | VAF 144/444 reads (32%) | called by mutect2, pindel, varscan2
- ADCY10 | c.666del p.N223Ifs*27 | Frame Shift Del (DEL) | VAF 44/150 reads (29%) | called by mutect2, pindel, varscan2
- ADNP2 | c.3135del p.K1045Nfs*29 | Frame Shift Del (DEL) | VAF 21/61 reads (34%) | called by mutect2, pindel, varscan2
- ADRA1A | c.122T>G p.V41G | Missense Mutation (SNP) | VAF 79/198 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- AGO4 | c.2094_2096del p.E698del | In Frame Del (DEL) | VAF 73/275 reads (27%) | called by pindel, varscan2
- AGTRAP | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AIFM1 | c.260C>A p.T87N | Missense Mutation (SNP) | VAF 86/181 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- AIMP2 | c.542A>T p.Y181F | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AK9 | c.724A>G p.K242E | Missense Mutation (SNP) | VAF 86/219 reads (39%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- AMZ2 | c.524T>C p.M175T | Missense Mutation (SNP) | VAF 111/366 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ANGEL1 | c.118del p.Q40Rfs*2 | Frame Shift Del (DEL) | VAF 56/145 reads (39%) | called by mutect2, pindel, varscan2
- ANGPTL2 | c.31C>A p.L11I | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ANK2 | c.9998T>C p.V3333A | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANK3 | c.3481dup p.L1161Pfs*13 (on ENST00000280772 / NM_001320874.2; = p.L295Pfs*13 on NM_001149.3) | Frame Shift Ins (INS) | VAF 28/99 reads (28%) | called by mutect2, pindel, varscan2
- ANKRD11 | c.2378_2380del p.K793del | In Frame Del (DEL) | VAF 73/218 reads (33%) | called by pindel, varscan2
- ANKRD35 | c.1091C>A p.P364H | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- ANKRD49 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- ANKRD50 | c.3704del p.P1235Hfs*8 | Frame Shift Del (DEL) | VAF 27/96 reads (28%) | called by mutect2, pindel, varscan2
- ANXA13 | c.247C>A p.L83I | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AOC3 | c.1751dup p.R585Sfs*60 | Frame Shift Ins (INS) | VAF 8/31 reads (26%) | called by mutect2, pindel, varscan2
- APOD | c.494del p.N165Ifs*3 | Frame Shift Del (DEL) | VAF 72/276 reads (26%) | called by mutect2, pindel, varscan2
- ARAP2 | c.1973+2T>C p.X658_splice | Splice Site (SNP) | VAF 36/104 reads (35%) | called by muse, varscan2
- ARFGAP3 | c.791T>C p.V264A | Missense Mutation (SNP) | VAF 151/414 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP30 | c.2623G>A p.A875T | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGAP5 | c.2676dup p.E893* | Frame Shift Ins (INS) | VAF 38/124 reads (31%) | called by mutect2, varscan2
- ARID1A | c.4130A>G p.Y1377C | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARL9 | c.620A>G p.D207G (on ENST00000640821 / NM_001363794.2; = p.D65G on NM_206919.2) | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARMCX3 | c.715C>T p.H239Y | Missense Mutation (SNP) | VAF 74/124 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- ARNT | c.1949A>G p.Q650R | Missense Mutation (SNP) | VAF 79/264 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- ARRDC4 | c.1140C>A p.C380* | Nonsense Mutation (SNP) | VAF 44/120 reads (37%) | called by muse, mutect2, varscan2
- ASB18 | c.174dup p.S59Lfs*32 | Frame Shift Ins (INS) | VAF 20/81 reads (25%) | called by mutect2, pindel, varscan2
- ASCC2 | c.1406A>G p.D469G | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ASPM | c.5039dup p.N1680Kfs*11 | Frame Shift Ins (INS) | VAF 66/232 reads (28%) | called by mutect2, pindel, varscan2
- ATP2A1 | c.859T>C p.S287P | Missense Mutation (SNP) | VAF 69/206 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ATP2B1 | c.1484A>G p.K495R | Missense Mutation (SNP) | VAF 92/261 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP2C2 | c.2501G>T p.S834I | Missense Mutation (SNP) | VAF 150/426 reads (35%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- BCAM | c.815G>A p.G272D | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.27); called by muse, mutect2
- BCL9L | c.3320T>C p.I1107T | Missense Mutation (SNP) | VAF 292/809 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- BHLHE41 | c.530del p.P177Rfs*4 | Frame Shift Del (DEL) | VAF 46/169 reads (27%) | called by mutect2, pindel, varscan2
- BUD31 | c.400T>C p.C134R | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- C11orf68 | c.227_228del p.V76Gfs*76 (on ENST00000530188; = p.V117Gfs*76 on NM_031450.4) | Frame Shift Del (DEL) | VAF 22/89 reads (25%) | called by pindel, varscan2
- C12orf40 | c.1570del p.M524* | Frame Shift Del (DEL) | VAF 65/217 reads (30%) | called by mutect2, pindel, varscan2
- C15orf39 | c.2389G>A p.A797T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- C16orf70 | c.131T>C p.V44A | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2
- C1QL4 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- C3 | c.198del p.K66Nfs*2 | Frame Shift Del (DEL) | VAF 71/272 reads (26%) | called by mutect2, pindel, varscan2
- CACNA1C | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 72/225 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CACNA1I | c.733T>C p.F245L | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CACNG7 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- CACUL1 | c.349A>C p.T117P | Missense Mutation (SNP) | VAF 71/282 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- CALML3 | c.343del p.E115Rfs*3 | Frame Shift Del (DEL) | VAF 46/160 reads (29%) | called by mutect2, pindel, varscan2
- CAPN7 | c.759del p.K253Nfs*21 | Frame Shift Del (DEL) | VAF 118/406 reads (29%) | called by mutect2, pindel, varscan2
- CARM1 | c.1134G>T p.M378I | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CASD1 | c.1226T>G p.I409S | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CATSPERE | c.256C>A p.P86T | Missense Mutation (SNP) | VAF 17/576 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); called by muse, mutect2
- CAV2 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CC2D1A | c.1028dup p.P344Tfs*59 | Frame Shift Ins (INS) | VAF 58/171 reads (34%) | called by mutect2, pindel, varscan2
- CCDC150 | c.1844A>G p.Q615R | Missense Mutation (SNP) | VAF 163/421 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC178 | c.1993del p.Y665Mfs*4 (on ENST00000383096 / NM_001105528.3; = p.Y627Mfs*4 on NM_198995.3) | Frame Shift Del (DEL) | VAF 175/578 reads (30%) | called by mutect2, pindel, varscan2
- CCL21 | c.116A>G p.K39R | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- CCP110 | c.837G>C p.Q279H | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- CD163 | c.2527del p.Y843Tfs*38 | Frame Shift Del (DEL) | VAF 27/95 reads (28%) | called by mutect2, pindel, varscan2
- CDC14A | c.889T>C p.Y297H | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- CDH16 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 166/441 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CDKN2D | c.334C>A p.H112N | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CDS1 | c.1256+2T>C p.X419_splice | Splice Site (SNP) | VAF 47/147 reads (32%) | called by muse, mutect2, varscan2
- CELA1 | c.266A>G p.Y89C | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- CELA3A | c.45C>A p.A15= | Splice Region (SNP) | VAF 34/104 reads (33%) | called by muse, mutect2, varscan2
- CELF2 | c.1256-10_1262delinsCCTCCTTAGGTCCAGAG p.X419_splice (on ENST00000416382 / NM_001025077.3; = p.X432_splice on NM_006561.3 and 2 other RefSeq transcripts) | Splice Site (ONP) | VAF 64/243 reads (26%) | called by mutect2*, pindel, varscan2*
- CERKL | c.74C>A p.A25D | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CHRD | c.2195A>G p.Q732R | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- CKAP5 | c.3748A>G p.T1250A | Missense Mutation (SNP) | VAF 101/271 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CLCN4 | c.1766A>G p.E589G | Missense Mutation (SNP) | VAF 52/88 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- CLSTN1 | c.662del p.N221Tfs*5 (on ENST00000377298 / NM_001009566.3; = p.N211Tfs*5 on NM_014944.4) | Frame Shift Del (DEL) | VAF 50/258 reads (19%) | called by mutect2, pindel, varscan2
- CNKSR1 | c.212G>A p.S71N | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- CNNM1 | c.932del p.G311Afs*51 | Frame Shift Del (DEL) | VAF 24/68 reads (35%) | called by mutect2, pindel, varscan2
- COL11A2 | c.798+2T>C p.X266_splice | Splice Site (SNP) | VAF 217/600 reads (36%) | called by muse, mutect2, varscan2
- COL14A1 | c.119T>C p.V40A | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.471); called by muse, varscan2
- COL21A1 | c.1811C>A p.P604H | Missense Mutation (SNP) | VAF 13/359 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- COL2A1 | c.2750del p.P917Lfs*111 | Frame Shift Del (DEL) | VAF 31/73 reads (42%) | called by mutect2, pindel, varscan2
- COL6A2 | c.2312A>C p.N771T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); called by mutect2, varscan2
- COL6A3 | c.8323G>A p.G2775S | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL9A2 | c.1144G>T p.G382C | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COLGALT2 | c.233T>C p.L78P | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- COPS3 | c.944del p.L315* | Frame Shift Del (DEL) | VAF 11/59 reads (19%) | called by mutect2, pindel, varscan2
- COPS9 | c.132del p.F44Lfs*43 (on ENST00000607357 / NM_001163424.2; = p.F75Lfs*57 on NM_138336.1) | Frame Shift Del (DEL) | VAF 38/104 reads (37%) | called by mutect2, pindel, varscan2
- COQ8A | c.1744_1745del p.S582Hfs*147 | Frame Shift Del (DEL) | VAF 20/74 reads (27%) | called by pindel, varscan2
- CORO1A | c.194G>A p.G65D | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CREBBP | c.4281-2A>G p.X1427_splice | Splice Site (SNP) | VAF 34/84 reads (40%) | called by muse, varscan2
- CSE1L | c.1630G>A p.A544T | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CTSH | c.875del p.N292Mfs*8 | Frame Shift Del (DEL) | VAF 48/180 reads (27%) | called by mutect2, pindel, varscan2
- CTTNBP2NL | c.773A>G p.N258S | Missense Mutation (SNP) | VAF 142/358 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CXorf66 | c.255dup p.G86Rfs*8 | Frame Shift Ins (INS) | VAF 43/77 reads (56%) | called by mutect2, pindel, varscan2
- CYP26B1 | c.740T>C p.L247P | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CYP27A1 | c.1424C>T p.A475V | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- DCC | c.2205G>T p.R735S | Missense Mutation (SNP) | VAF 66/200 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DCTN3 | c.397C>A p.H133N | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- DDB1 | c.2413C>T p.H805Y | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT tolerated (0.68); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- DDX39B | c.447del p.F149Lfs*13 | Frame Shift Del (DEL) | VAF 18/42 reads (43%) | called by mutect2, varscan2
- DDX54 | c.327A>C p.K109N | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- DEAF1 | c.722A>G p.E241G | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DENND4A | c.3468del p.K1156Nfs*49 | Frame Shift Del (DEL) | VAF 61/217 reads (28%) | called by mutect2, pindel, varscan2
- DGKB | c.667G>T p.G223* | Nonsense Mutation (SNP) | VAF 14/77 reads (18%) | called by muse, mutect2, varscan2
- DHODH | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 72/202 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DIPK2A | c.62T>C p.L21P | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- DLG2 | c.634G>T p.G212W | Missense Mutation (SNP) | VAF 75/224 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH11 | c.13430A>G p.E4477G | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- DNAI2 | c.1349T>C p.V450A | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- DNER | c.2012G>A p.G671D | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DPF2 | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 28/94 reads (30%) | called by muse, mutect2, varscan2
- DPH5 | c.799C>A p.L267I | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.677); called by muse, varscan2
- DPP10 | c.1312del p.I438Ffs*4 | Frame Shift Del (DEL) | VAF 99/329 reads (30%) | called by mutect2, pindel, varscan2
- DPP6 | c.1237G>A p.A413T (on ENST00000377770 / NM_001364500.2; = p.A351T on NM_001936.5) | Missense Mutation (SNP) | VAF 75/178 reads (42%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- DST | c.2566_2568del p.E856del (on ENST00000361203 / NM_001374722.1; = p.E530del on NM_001723.6) | In Frame Del (DEL) | VAF 71/303 reads (23%) | called by pindel, varscan2
- DUSP23 | c.205C>G p.P69A | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- DYNC2H1 | c.4451T>C p.V1484A | Missense Mutation (SNP) | VAF 135/376 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- EAF1 | c.344G>A p.G115D | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EFEMP2 | c.533T>C p.V178A | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EID1 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 55/176 reads (31%) | called by muse, mutect2, varscan2
- EIF1B | c.325A>T p.K109* | Nonsense Mutation (SNP) | VAF 42/142 reads (30%) | called by muse, mutect2, varscan2
- ELP3 | c.380A>G p.Y127C | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EMID1 | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ENG | c.771dup p.Y258Lfs*76 | Frame Shift Ins (INS) | VAF 60/196 reads (31%) | called by mutect2, pindel, varscan2
- EPC2 | c.207del p.E70Rfs*39 | Frame Shift Del (DEL) | VAF 136/446 reads (30%) | called by mutect2, varscan2
- EPHA5 | c.1513A>G p.K505E | Missense Mutation (SNP) | VAF 114/282 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, varscan2
- EPHX2 | c.548del p.L183Wfs*8 | Frame Shift Del (DEL) | VAF 20/82 reads (24%) | called by mutect2, pindel, varscan2
- ERF | c.970T>A p.Y324N | Missense Mutation (SNP) | VAF 110/309 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- EXOC4 | c.2741T>C p.V914A | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- FAM110D | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM133A | c.157dup p.T53Nfs*8 | Frame Shift Ins (INS) | VAF 87/142 reads (61%) | called by mutect2, varscan2
- FAM181B | c.1009del p.L337* | Frame Shift Del (DEL) | VAF 28/64 reads (44%) | called by mutect2, pindel, varscan2
- FAM189B | c.857_859del p.S286del | In Frame Del (DEL) | VAF 42/96 reads (44%) | called by pindel, varscan2
- FAM217A | c.1075T>C p.S359P | Missense Mutation (SNP) | VAF 67/223 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- FAM47A | c.2168del p.K723Sfs*22 | Frame Shift Del (DEL) | VAF 123/231 reads (53%) | called by mutect2, pindel, varscan2
- FAM83D | c.1334A>T p.D445V | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FBN3 | c.8390del p.G2797Afs*4 | Frame Shift Del (DEL) | VAF 36/114 reads (32%) | called by mutect2, pindel, varscan2
- FBXO5 | c.777A>T p.L259F | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXO7 | c.1118G>A p.R373K | Missense Mutation (SNP) | VAF 153/509 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FETUB | c.953del p.K318Rfs*13 | Frame Shift Del (DEL) | VAF 40/133 reads (30%) | called by mutect2, pindel, varscan2
- FIGNL1 | c.1391G>C p.S464T | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FILIP1 | c.2861T>C p.I954T | Missense Mutation (SNP) | VAF 157/495 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FKTN | c.76T>C p.Y26H | Missense Mutation (SNP) | VAF 114/284 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FLYWCH1 | c.1871G>T p.G624V (on ENST00000253928 / NM_001308068.2; = p.G623V on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/173 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FMN2 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- FMNL3 | c.2755G>T p.V919F | Missense Mutation (SNP) | VAF 93/254 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- FRK | c.1425G>T p.K475N | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FRMD3 | c.568del p.I190* | Frame Shift Del (DEL) | VAF 66/241 reads (27%) | called by mutect2, pindel, varscan2
- FRMPD1 | c.3359del p.N1120Mfs*38 | Frame Shift Del (DEL) | VAF 59/171 reads (35%) | called by mutect2, pindel, varscan2
- FSCB | c.635dup p.N212Kfs*12 | Frame Shift Ins (INS) | VAF 75/234 reads (32%) | called by mutect2, pindel, varscan2
- FTO | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 80/215 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- FYB1 | c.848del p.K283Rfs*6 | Frame Shift Del (DEL) | VAF 183/534 reads (34%) | called by mutect2, varscan2
- GABRA5 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GAD2 | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GALNT14 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 149/389 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GBP6 | c.16A>T p.K6* | Nonsense Mutation (SNP) | VAF 68/177 reads (38%) | called by muse, mutect2, varscan2
- GCC1 | c.2107C>T p.Q703* | Nonsense Mutation (SNP) | VAF 190/587 reads (32%) | called by muse, mutect2, varscan2
- GGA2 | c.253-1G>T p.X85_splice | Splice Site (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- GLP1R | c.1258T>C p.W420R | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- GLRX3 | c.992T>C p.L331P | Missense Mutation (SNP) | VAF 238/674 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GNA12 | c.793A>G p.R265G | Missense Mutation (SNP) | VAF 89/265 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GOLGA4 | c.1339del p.T447Qfs*13 | Frame Shift Del (DEL) | VAF 273/1051 reads (26%) | called by mutect2, pindel, varscan2
- GOLGA5 | c.608C>G p.S203* | Nonsense Mutation (SNP) | VAF 47/123 reads (38%) | called by muse, mutect2, varscan2
- GOSR2 | c.80T>C p.F27S (on ENST00000393456 / NM_001321134.1; = p.F45S on NM_004287.5) | Missense Mutation (SNP) | VAF 98/275 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GPNMB | c.1207C>T p.P403S (on ENST00000381990 / NM_001005340.2; = p.P391S on NM_002510.3) | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.8); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GPR141 | c.328C>A p.L110M | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GPR176 | c.245del p.N82Tfs*49 | Frame Shift Del (DEL) | VAF 25/69 reads (36%) | called by mutect2, pindel, varscan2
- GPR37 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- GPRIN1 | c.2104del p.T702Rfs*12 | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | called by mutect2, pindel, varscan2
- GRAP | c.149A>C p.K50T | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); called by mutect2, varscan2
- GRHL2 | c.1625T>G p.V542G | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GSE1 | c.3278del p.P1093Qfs*45 | Frame Shift Del (DEL) | VAF 33/94 reads (35%) | called by mutect2, pindel, varscan2
- GTF2B | c.265G>T p.G89* | Nonsense Mutation (SNP) | VAF 46/143 reads (32%) | called by muse, mutect2, varscan2
- HAPLN4 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- HAUS3 | c.595dup p.S199Ffs*30 | Frame Shift Ins (INS) | VAF 48/177 reads (27%) | called by mutect2, pindel, varscan2
- HAUS6 | c.836T>C p.L279P | Missense Mutation (SNP) | VAF 64/287 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- HDAC4 | c.2134C>T p.Q712* | Nonsense Mutation (SNP) | VAF 126/309 reads (41%) | called by muse, mutect2, varscan2
- HEATR1 | c.2810C>A p.A937D | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- HINFP | c.1475del p.P492Qfs*17 | Frame Shift Del (DEL) | VAF 25/71 reads (35%) | called by mutect2, pindel, varscan2
- HIVEP2 | c.6974dup p.N2325Kfs*44 | Frame Shift Ins (INS) | VAF 71/242 reads (29%) | called by mutect2, pindel, varscan2
- HMCN1 | c.5068A>G p.I1690V | Missense Mutation (SNP) | VAF 83/207 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- HNRNPA2B1 | c.937_939del p.Y313del (on ENST00000354667 / NM_031243.3; = p.Y301del on NM_002137.4) | In Frame Del (DEL) | VAF 51/203 reads (25%) | called by mutect2, pindel, varscan2
- HNRNPDL | c.1033A>T p.N345Y | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.641); called by muse, mutect2
- HRH2 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 129/331 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- HSPA2 | c.1916A>G p.D639G | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, varscan2
- HSPD1 | c.606G>T p.K202N | Missense Mutation (SNP) | VAF 72/210 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- HSPE1-MOB4 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 125/346 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); called by muse, mutect2, varscan2
665 further variants in this file (305 protein-altering or splice-affecting, 334 silent, 26 other) are not listed here.
